Gene-level copy-number profile of tumor specimen TCGA-AZ-6606-01A from TCGA case TCGA-AZ-6606, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 81.3 years (29,704 days).
Specimen TCGA-AZ-6606-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.9958d8f5-1f27-4e14-a472-6c401d567357.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AZ-6606-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9f0e5f1f-c720-4a64-8618-d29764040c94

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 13; copy number 2: 2,220; copy number 3: 714; copy number 4: 44,965; copy number 5: 2,798; copy number 6: 3,744; copy number 7: 555; copy number 8: 2,798; copy number 9: 324; copy number 11: 96; copy number 12: 20; copy number 13: 1,346; copy number 14: 75; copy number 15: 42; copy number 16: 3; copy number 20: 27; copy number 42: 65; copy number 58: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AZ-6606-01A-11D-1834-01): tumor purity 0.8, ploidy 2.32, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,013 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,577,187–43,085,788, 42 genes, copy number 15 (within-gene range 2–15): GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P.
- chr8:115,408,496–123,290,503, 94 genes, copy number 11–16 (broad region; genes not listed).
- chr12:66,767–5,521,536, 136 genes, copy number 13–58 (broad region; genes not listed).
- chr12:5,583,797–5,584,085, 1 gene, copy number 13: AC137627.1.
- chr12:9,347,056–9,400,387, 1 gene, copy number 12 (within-gene range 4–12): LINC02367.
- chr12:9,398,355–9,895,833, 24 genes, copy number 11–12: AC141557.1, AC141557.2, DDX12P, SNORA75, AC092821.3, AC092821.1, AC092821.2, KLRB1, RNU6-700P, GOT2P3, AC010186.4, AC010186.1, AC010186.2, AC010186.3, CLEC2D, NPM1P7, LINC02390, CLECL1, CD69, GCNAP1, KLRF1, CLEC2B, AC091814.1, KLRF2.
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 13–14 (broad region; genes not listed).
- chr19:6,467,207–6,482,557, 1 gene, copy number 9 (within-gene range 5–9): DENND1C.
- chr19:6,494,319–12,441,082, 323 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
